Somatic mutation profile of tumor specimen 0DGOAW from CCDI case PBBTTH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 9.7 years (3,557 days).
Specimen 0DGOAW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e31b52f9-5a7d-45a1-a144-a62ff3db19d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGOB0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fce57de7-d69c-4495-bc1a-06999826ea4f

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Intron 2, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 143/748 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 359/776 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FAM155A | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 203/737 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101031023; called by muse, mutect2, varscan2
- FAM83A | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 102/465 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs145588458; called by muse, mutect2, varscan2
- KIF13A | c.1139A>T p.Q380L | Missense Mutation (SNP) | VAF 23/596 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.465); catalogued as rs1252217511; called by muse, mutect2
- LRFN5 | c.1735C>A p.Q579K | Missense Mutation (SNP) | VAF 298/790 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV53269343; called by muse, varscan2
- RBM28 | c.1641C>G p.F547L | Missense Mutation (SNP) | VAF 222/733 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs989011649, COSV56161749; called by muse, mutect2, varscan2
- TLK1 | c.2275C>G p.P759A | Missense Mutation (SNP) | VAF 132/570 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs367836334, COSV62632414; called by muse, mutect2, varscan2
- EVPL | c.5427_5428del p.S1810Ffs*12 | Frame Shift Del (DEL) | VAF 82/383 reads (21%) | called by pindel, varscan2
- EXD2 | c.115G>T p.V39L | Missense Mutation (SNP) | VAF 32/526 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- HNRNPCL4 | c.229A>G p.S77G | Missense Mutation (SNP) | VAF 165/531 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBD5 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 24/730 reads (3%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- RETREG3 | c.1396C>T p.H466Y | Missense Mutation (SNP) | VAF 100/354 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 18/268 reads (7%) | catalogued as rs1167537044; called by muse, mutect2
- SIN3B | c.2682G>A p.A894= | Silent (SNP) | VAF 107/376 reads (28%) | catalogued as rs371975490; called by muse, mutect2, varscan2
- TACC2 | c.5802C>T p.P1934= | Silent (SNP) | VAF 36/476 reads (8%) | called by muse, mutect2
- BCL11A | chr2:60452518 C>T | 3'Flank (SNP) | VAF 62/176 reads (35%) | catalogued as rs1200029595; called by muse, mutect2, varscan2
- SLCO6A1 | c.1815-86A>C | Intron (SNP) | VAF 50/154 reads (32%) | called by muse, varscan2
- TTC8 | c.459+44T>A | Intron (SNP) | VAF 34/614 reads (6%) | called by muse, mutect2
